Gene-level copy-number profile of tumor specimen HCM-WCMC-0671-C18-01A from HCMI case HCM-WCMC-0671-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,322 days).
Specimen HCM-WCMC-0671-C18-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4367dda1-a809-4edc-abd7-172fe48900f9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0671-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/0fa7d580-d1f9-47e9-b28a-d3d09b7365b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 12,513; copy number 2: 33,957; copy number 3: 10,462; copy number 4: 869; copy number 5: 539; copy number 6: 28.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,699,456–143,760,669, 5 genes: RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr1:143,784,376–143,825,837, 4 genes: AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr1:144,085,628–144,373,659, 8 genes: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–1): MIR4634.
- chr13:53,028,813–53,052,057, 1 gene: OLFM4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 567 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:97,644,184–97,772,425, 2 genes, copy number 5: MTDH, Y_RNA.
- chr12:280,057–5,521,536, 119 genes, copy number 5–6 (broad region; genes not listed).
- chr20:30,484,925–37,179,588, 221 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:43,457,893–47,827,044, 154 genes, copy number 5 (broad region; genes not listed).
- chr20:49,503,874–52,204,308, 60 genes, copy number 5: PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr20:53,544,615–53,875,557, 7 genes, copy number 5: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5 (within-gene range 2–6): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 6: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 11,748. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
